CGCI case BLGSP-71-06-00091 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ad1b4563-3d9e-4d1d-993f-28e0e35c750b

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 7 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Mandible; Classification of tumor: primary; Age at diagnosis: 7.2 years (2,619 days); Year of diagnosis: 2014; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 133 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Endemic; Max tumor bulk site: Mandible; Sites of involvement: Eye / Mandible.
   Pathology details: Lymph node involved site: Inguinal; Tumor largest dimension diameter: 8 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: COM; Days to treatment start: 7 days; Days to treatment end: 145 days; Number of cycles: 9.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Methotrexate + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 7 days; Days to treatment end: 145 days; Number of cycles: 9.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 60; ECOG performance status: 3.
- Days to follow up: 117 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 117 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 133 days; Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 1168 [Blood test normal range upper: 298].

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-06-00091-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Mandible; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Incisional Biopsy; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00091-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 30; Percent tumor nuclei: 40; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 70; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 10.
  Slide BLGSP-71-06-00091-01A-01-S1-HE: Section location: Top; Percent tumor cells: 10; Percent tumor nuclei: 30; Percent normal cells: 80; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-06-00091-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-06-00091-99A: Sample type: Granulocytes; Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Blood Draw; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Lymph nodes examined: No.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Eye.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 1168; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- Follow-up form 1: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 2: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: Yes.
- Follow-up form 2, New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site: Lymph Node(s); New tumor event diagnosis evidence: Convincing Imaging; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 9.
